Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RJ, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RJ-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinosarcoma, Mixed
Mullerian Tumor, malignant
8950/3
Site: Endometrium, C54.1
JW 4/2/13

Specimens Submitted:

- 1: Lymph node, Right periaorti, excision (fs)
- 2: Cervix, uterus, bilateral fallopian tubes and ovaries, total hysterectomy and bilateral salpingo-oophorectomy
- 3: SP: Omentum

DIAGNOSIS:

1. Lymph node, Right periaorti, excision (fs):
Lymph Nodes:
Number of nodes examined: 3
Number of metastatic nodes: 3
Metastatic tumor is composed of epithelial component of
carcinosarcoma.

-
2. Cervix, uterus, bilateral fallopian tubes and ovaries, total hysterectomy and bilateral salpingo-oophorectomy:
Tumor Type:
Carcinosarcoma (Malignant mullerian mixed tumor) of endometrium with heterologous differentiation
Arising from endometrial polyp
Myometrial Invasion:
(= $\leq$ 50%)
Measures 1mm in maximum depth
Myometrium thickness measures 18mm in the area of maximal tumor
invasion
Endocervical Invasion:
Mucosa and stroma
Depth of cervical stromal invasion:
Measures 1.5mm
Cervical wall thickness measures 8mm in the area of maximum tumor
invasion
Lymphovascular invasion:
Not identified
Endometrium:
Unremarkable

** Continued on next page **

[page 2 of 2]
[REDACTED]

Myometrium:

Exhibits adenomyosis

Adnexa:

Unremarkable

3. OMENTUM, EXCISION:

- METASTATIC SEROUS ADENOCARCINOMA TO THE OMENTUM.
- TWO BENIGN LYMPH NODES (0/2).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

*** Report Electronically Signed Out *** [REDACTED]

[REDACTED]

History Discrepancy		✓
Immunohistochemistry		✓
Pathology History		✓
Primary Notes		

Source: NCI Genomic Data Commons file b6b52d2c-ba8c-4a23-91af-dbd1b75dbb88 (TCGA-N5-A4RJ.5885F0D2-678E-4294-99EE-E0EC7046FC84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).